TARGET case TARGET-21-PASSLT — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8c259503-61e8-531f-ac55-738d0456b1e6

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 14 years; Vital status: Dead; Days to death: 87 days.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 14.8 years (5,405 days); Year of diagnosis: 2009; Days to last follow up: 87 days.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Protocol identifier: AAML0531.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Gemtuzumab Ozogamicin.

Follow-up (2 entries)
- Days to follow up: 36 days; Days to first event: 36 days; First event: Induction Failure.
- Days to follow up: 87 days; Year of follow up: 2009.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- CEBPA mutation, nos: Negative.
- FLT3 internal tandem duplication: Negative.
- KMT2A translocation: Positive.
- MLLT10–PICALM fusion: Positive.
- Monosomy 5: Negative.
- Monosomy 7: Negative.
- NPM1 mutation, nos: Negative.
- Test: Negative.
- Test: Negative; Chromosomal translocation: t(11;19)(q23;p13.1).
- Test: Negative; Chromosomal translocation: t(3;5)(q25;q34).
- Test: Negative; Chromosomal translocation: t(6;11)(q27;q23).
- Test: Negative; Chromosomal translocation: t(6;9).
- Test: Negative; Chromosomal translocation: t(8;21).
- Test: Negative; Chromosomal translocation: t(9;11)(p22;q23).
- Test: Negative; Chromosome arm: q.
- Test: Positive; Chromosomal translocation: t(10;11)(p11.2;q23).
- Trisomy 21: Negative.
- Trisomy 8: Negative.
- WT1 mutation, nos: Negative.
- Day 0: Leukocytes 115 ×10³/µL; Blast Count 94%; Bone Marrow blast count 96%.
- Minimal Residual Disease (Flow Cytometry): Positive.

Biospecimens (4 samples)
- Sample TARGET-21-PASSLT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-21-PASSLT-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
- Sample TARGET-21-PASSLT-15A: Sample type: Fibroblasts from Bone Marrow Normal; Tissue type: Normal; Specimen type: Fibroblasts from Bone Marrow.
- Sample TARGET-21-PASSLT-41A: Sample type: Blood Derived Cancer - Bone Marrow, Post-treatment; Tissue type: Tumor; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_Discovery_20230720.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 87
- WBC at Diagnosis: 114.7
- Bone marrow leukemic blast percentage (%): 96
- Peripheral blasts (%): 94
- CNS disease: No
- Chloroma: No
- FAB Category: M0 Undifferentiated
- t(6;9): No
- t(8;21): No
- t(3;5)(q25;q34): No
- t(6;11)(q27;q23): No
- t(9;11)(p22;q23): No
- t(10;11)(p11.2;q23): Yes
- t(11:19)(q23:p13.1): No
- inv(16): No
- del5q: No
- del7q: No
- del9q: No
- monosomy 5: No
- monosomy 7: No
- trisomy 8: No
- trisomy 21: No
- MLL: Yes
- Minus Y: No
- Minus X: No
- Cytogenetic Code Other: t(10;11)(p13;q14)
- Cytogenetic Complexity: More than 6
- Primary Cytogenetic Code: MLL
- ISCN: 46,XY,t(10;11)(p13;q14),der(17)t(17;17)(p13;q21),del(12)(p12),+2 mar[4]/48,idem,t(13;15)(q32;q13)[11]/48,idem,add(3)(p12),der(4)inv(4)(q12q25)add(4)(q25),-del(12),der(13)(13pter->13q34::?3p21->3p13::4q25->4qter)[5]
- FLT3/ITD positive?: No
- FLT3 PM: No
- NPM mutation: No
- CEBPA mutation: No
- WT1 mutation: No
- MRD at end of course 1: Yes
- MRD % at end of course 1: 61
- CR status at end of course 1: not in CR
- CR status at end of course 2: not in CR
- Risk group: Standard Risk
- Bone Marrow Site of Relapse/Induction Failure: No
- CNS Site of Relapse/Induction Failure: Yes
- Chloroma Site of Relapse/Induction Failure: No
- Cytogenetic Site of Relapse/Induction Failure: No
- Other Site of Relapse/Induction Failure: No
- Gene Fusion: MLLT10-PICALM
- Gemtuzumab ozogamicin treatment: Gentuzumab ozogamicin treatment
- Refractory Timepoint sent for Induction Failure Project: EOI I

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_LowDepthRNAseq_20230720.xlsx (sheet Clinical Data):
- Primary Cytogenetic Code: Other
- Blast count used for RNA seq: 96
- Gene Fusion: MLLT10:PICALM
